Gene-level copy-number profile of tumor specimen TARGET-10-PARPUL-09A from TARGET case TARGET-10-PARPUL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (820 days).
Specimen TARGET-10-PARPUL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.c8de9e24-eb82-5965-b22a-e29cbd22ed60.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PARPUL-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 397 have no estimate.
https://portal.gdc.cancer.gov/files/6da55f43-5d38-4b70-9d6f-40039adb71e2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,511; copy number 1: 1,720; copy number 2: 54,499; copy number 3: 1,360; copy number 4: 13; copy number 5: 88; copy number 6: 8; copy number 7: 2; copy number 8: 25.

Homozygous deletions (total copy number 0; autosomes only): 130 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,300,322, 8 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.
- chr7:142,544,212–142,786,224, 31 genes: TRBV10-3, TRBV11-3, TRBV12-3, TRBV12-4, TRBV12-5, TRBV14, TRBV15, TRBV16, TRBV17, TRBV18, TRBV19, TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1.
- chr9:21,966,929–22,455,740, 10 genes: CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.
- chr14:22,163,238–22,530,378, 75 genes (broad region; genes not listed).
- chr16:81,053,497–81,096,296, 2 genes (within-gene range 0–2): C16orf46, AC092718.3.
- chr16:81,069,854–81,078,861, 2 genes: AC092718.6, AC092718.1.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 123 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:234,535,963–234,554,838, 2 genes, copy number 5: AL161640.2, AL161640.3.
- chr1:237,471,119–237,471,191, 1 gene, copy number 6: MIR4428.
- chr2:88,857,161–89,117,844, 24 genes, copy number 8: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17.
- chr5:135,802,985–135,827,546, 2 genes, copy number 6: MIR5692C1, AC114296.1.
- chr6:167,975,924–168,101,511, 4 genes, copy number 6: HGC6.3, KIF25-AS1, KIF25, FRMD1.
- chr8:27,459,756–27,479,883, 1 gene, copy number 5: CHRNA2.
- chr10:21,110,682–21,113,388, 1 gene, copy number 6: NPM1P30.
- chr13:106,773,623–106,774,279, 1 gene, copy number 5: AL162574.2.
- chr15:24,978,583–25,420,336, 1 gene, copy number 5 (within-gene range 2–5): SNHG14.
- chr15:25,041,974–25,257,027, 82 genes, copy number 5 (broad region; genes not listed).
- chr15:76,586,647–76,586,691, 1 gene, copy number 8: MIR3713.
- chr17:46,035,313–46,035,770, 1 gene, copy number 5: CR936218.1.
- chr19:19,740,884–19,750,127, 1 gene, copy number 7: AC011477.6.
- chr19:19,750,618–19,752,544, 1 gene, copy number 7 (within-gene range 2–7): AC011477.5.

Autosomal genes at a single copy (total copy number 1): 1,712. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
